Somatic mutation profile of tumor specimen MP2PRT-PARLEF-TMP1-A (aliquot MP2PRT-PARLEF-TMP1-A-1-0-D-A834-36) from MP2PRT case MP2PRT-PARLEF, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.2 years (1,517 days).
Specimen MP2PRT-PARLEF-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 61efc0af-4bae-456e-ac86-292e56325f1f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PARLEF-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PARLEF-NB1-A-1-0-D-A834-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b0142b20-5f23-49b3-8087-74a7a3e31f85

The open-access MAF lists 8 somatic variants for this specimen: 4 protein-altering or splice-affecting, 4 silent.
By variant classification: Silent 4, Missense Mutation 3, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KCNQ1 | c.1190G>A p.R397Q | Missense Mutation (SNP) | VAF 155/753 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.389); catalogued as rs374090960, CM150594; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- NBEAL2 | c.6796G>A p.A2266T | Missense Mutation (SNP) | VAF 95/452 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLC16A9 | c.948_949insCAACA p.D317Qfs*16 | Frame Shift Ins (INS) | VAF 29/160 reads (18%) | called by mutect2, pindel*, varscan2
- ZNF541 | c.1370C>T p.S457L | Missense Mutation (SNP) | VAF 271/1129 reads (24%) | SIFT tolerated (0.14); PolyPhen benign (0); called by muse, mutect2, varscan2
- CASKIN1 | c.1218C>T p.H406= | Silent (SNP) | VAF 253/1110 reads (23%) | catalogued as rs751511290; called by muse, mutect2, varscan2
- KRT32 | c.1338C>T p.G446= | Silent (SNP) | VAF 100/390 reads (26%) | catalogued as COSV56788348; called by muse, varscan2
- MARCHF1 | c.648C>T p.Y216= (on ENST00000274056; = p.Y199= on NM_017923.4) | Silent (SNP) | VAF 121/504 reads (24%) | catalogued as rs201136702, COSV99920636; called by muse, mutect2, varscan2
- RIMBP2 | c.1704C>T p.S568= | Silent (SNP) | VAF 74/1111 reads (7%) | catalogued as rs753678065, COSV55464945; called by muse, mutect2
